Somatic mutation profile of tumor specimen TARGET-10-PAPAGF-09A (aliquot TARGET-10-PAPAGF-09A-01D) from TARGET case TARGET-10-PAPAGF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,390 days).
Specimen TARGET-10-PAPAGF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ce62a09-4e17-4929-9aa4-fc70f150f2b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAGF-10A (Blood Derived Normal), aliquot TARGET-10-PAPAGF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09b49192-305c-4de6-bdc4-188dbbb37193

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.7514C>T p.S2505L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as rs752860826; called by muse, varscan2
- CENPI | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV99515576; called by muse, mutect2
- PCDHA9 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.024); catalogued as rs140660802; called by muse, mutect2, varscan2
- CELA1 | c.7_16+22delinsCGCTTCCTGGTGTGCT p.X3_splice | Splice Site (DEL) | VAF 5/34 reads (15%) | called by mutect2*, pindel
- CIZ1 | c.2368G>T p.V790L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.044); called by muse, mutect2
- KIAA1549L | c.1132T>C p.S378P (on ENST00000321505; = p.S675P on NM_012194.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- NLRC5 | c.5442G>T p.W1814C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PI4K2A | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PPAN-P2RY11 | c.806C>A p.A269E | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RACGAP1 | c.1823+1G>T p.X608_splice | Splice Site (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- ADAM11 | c.2037C>A p.G679= | Silent (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- DAXX | c.1227C>T p.P409= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as rs766894986; called by muse, mutect2, varscan2
- NPAS3 | c.909C>T p.T303= (on ENST00000356141 / NM_001164749.2; = p.T271= on NM_022123.3) | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs746089574; called by muse, mutect2, varscan2
- RBM20 | c.696C>A p.G232= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1219073487; called by muse, mutect2
- RDH10 | c.495C>A p.T165= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
